Gene-level copy-number profile of tumor specimen TCGA-E1-A7YL-01A from TCGA case TCGA-E1-A7YL, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 46.5 years (16,982 days).
Specimen TCGA-E1-A7YL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.c84edf9f-dc6b-4e44-9f5b-5d060ae14393.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E1-A7YL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/49423205-d89a-43f3-9681-f1e9bbeee040

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,951; copy number 2: 44,398; copy number 3: 6,131; copy number 4: 55; copy number 5: 12; copy number 7: 71; copy number 9: 44; copy number 11: 48; copy number 13: 110.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E1-A7YL-01A-11D-A349-01): tumor purity 0.53, ploidy 3.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 285 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,164,008–184,780,720, 158 genes, copy number 11–13 (broad region; genes not listed).
- chr12:57,431,116–57,896,846, 44 genes, copy number 9: AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3.
- chr18:28,638,714–35,143,470, 82 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr18:38,655,209–38,688,033, 1 gene, copy number 5: AC100781.1.

Autosomal genes at a single copy (total copy number 1): 6,570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
